Gene-level copy-number profile of tumor specimen MP2PRT-PASYKN-TTM2-A from MP2PRT case MP2PRT-PASYKN, project MP2PRT-WT (Molecular Profiling to Predict Response to Treatment - Wilms Tumor). Sex at birth: female; Vital status: Alive; Primary diagnosis: Nephroblastoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 3.5 years (1,276 days).
Specimen MP2PRT-PASYKN-TTM2-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9f78abe8-307b-412c-a192-e033322d155f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PASYKN-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,219 have no estimate.
https://portal.gdc.cancer.gov/files/f93e05a3-6d8e-4405-8673-60011582a910

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 4,414; copy number 2: 50,722; copy number 3: 730; copy number 5: 2,524.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:32,064,912–32,085,712, 3 genes (within-gene range 0–1): AL035078.2, U3, EIF4A2P5.
- chr11:32,097,143–32,458,769, 11 genes (within-gene range 0–1): AL078612.1, THEM7P, AL078612.2, WT1, WT1-AS, AL049692.6, AL049692.1, AL049692.5, AL049692.3, AL049692.2, AL049692.4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,524 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–248,937,043, 2,524 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4,414. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
